Somatic mutation profile of tumor specimen 0E1KOG from CCDI case PBCWPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1KOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e1eefac-75b0-4806-86cc-707871c6eab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1KO9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8718cfbf-20d1-4101-8cb7-5e30281d0f79

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOD1 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 188/284 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452486; called by muse, varscan2
- BCR | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs1396864304; called by muse, varscan2
- RNF152 | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 130/388 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV99080538; called by muse, varscan2
- UROC1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 56/480 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as rs1010838044; called by muse, varscan2
- EFCAB6 | c.4425C>A p.F1475L | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.86); called by muse, varscan2
- GGT6 | c.715G>T p.D239Y (on ENST00000574154 / NM_001122890.3; = p.D207Y on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- GPRASP1 | c.786G>T p.W262C | Missense Mutation (SNP) | VAF 206/219 reads (94%) | SIFT tolerated (0.85); PolyPhen benign (0.005); called by muse, varscan2
- MS4A14 | c.1748A>T p.D583V | Missense Mutation (SNP) | VAF 130/646 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); called by muse, varscan2
- MUC3A | c.4948A>G p.T1650A | Missense Mutation (SNP) | VAF 96/770 reads (12%) | SIFT tolerated, low confidence (0.26); called by muse, varscan2
- PLEK | c.386T>C p.L129S | Missense Mutation (SNP) | VAF 352/651 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- TGFBR1 | c.190A>C p.K64Q | Missense Mutation (SNP) | VAF 117/473 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, varscan2
- CADPS | c.3744C>G p.V1248= | Silent (SNP) | VAF 254/644 reads (39%) | called by muse, varscan2
- APBA3 | c.1516-22G>A | Intron (SNP) | VAF 125/432 reads (29%) | catalogued as rs760692286; called by muse, varscan2
- S1PR3 | c.-369C>G | 5'UTR (SNP) | VAF 79/231 reads (34%) | called by muse, varscan2
